Somatic mutation profile of tumor specimen TCGA-13-0723-01A (aliquot TCGA-13-0723-01A-02W-0372-09) from TCGA case TCGA-13-0723, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.2 years (23,094 days).
Specimen TCGA-13-0723-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2d85af9-b95e-47d0-8b06-1466e55119fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0723-10B (Blood Derived Normal), aliquot TCGA-13-0723-10B-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34ea6ae2-ce94-43ab-a5fd-9cf48822d86b

The open-access MAF lists 59 somatic variants for this specimen: 42 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 14, Nonsense Mutation 4, Frame Shift Ins 2, RNA 2, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.448_460del p.T150Afs*16 | Frame Shift Del (DEL) | VAF 56/86 reads (65%) | catalogued as rs1064792930, COSV52702198; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ARHGEF1 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs1305546842, COSV100528947, COSV61526205; called by muse, mutect2, varscan2
- ARHGEF7 | c.2039T>G p.M680R (on ENST00000375741 / NM_001113511.2; = p.M502R on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV54538658; called by muse, mutect2, varscan2
- ASGR2 | c.755A>G p.Y252C | Missense Mutation (SNP) | VAF 39/272 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54689217; called by muse, mutect2, varscan2
- BPIFB3 | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV64956726; called by muse, mutect2, varscan2
- CABIN1 | c.4649G>A p.R1550H | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776094414, COSV54077400, COSV54081236; called by muse, mutect2, varscan2
- CEP350 | c.5218C>T p.R1740W | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1335053833, COSV62598697; called by muse, mutect2, varscan2
- EEF2KMT | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as rs200021489; called by muse, mutect2, varscan2
- EHD2 | c.1101C>G p.D367E | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV54406640; called by muse, mutect2, varscan2
- FREM2 | c.6942A>T p.E2314D | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.519); catalogued as COSV54827904; called by muse, mutect2, varscan2
- GAL3ST4 | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 48/143 reads (34%) | catalogued as COSV57585203; called by muse, mutect2, varscan2
- GBA2 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747345187, COSV62305207, COSV62305224; called by muse, mutect2, varscan2
- GPR142 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as COSV59518503; called by muse, mutect2, varscan2
- GRHL2 | c.481_482insT p.E161Vfs*28 | Frame Shift Ins (INS) | VAF 103/292 reads (35%) | catalogued as COSV52544289; called by mutect2, pindel, varscan2
- H2BC4 | c.18G>T p.K6N | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1272699382, COSV58414875, COSV58415034; called by muse, mutect2, varscan2
- KIAA1210 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1450500200; called by muse, mutect2, varscan2
- KRT72 | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 78/307 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs956755555, COSV53373139; called by muse, mutect2, varscan2
- LAMC3 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs141325432; called by muse, mutect2, varscan2
- MAP3K4 | c.3199A>G p.I1067V | Missense Mutation (SNP) | VAF 187/425 reads (44%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.977); catalogued as COSV62330050; called by muse, mutect2, varscan2
- MORC1 | c.1237A>G p.N413D | Missense Mutation (SNP) | VAF 50/1205 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as rs373695498; called by muse, mutect2
- MRPL42 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 87/296 reads (29%) | catalogued as COSV62355514; called by muse, mutect2, varscan2
- NEUROD6 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs1342645399, COSV51769921; called by muse, mutect2, varscan2
- NFATC1 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs201990048, COSV53694964; called by muse, mutect2, varscan2
- OBSCN | c.4528G>A p.G1510R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375200221; called by muse, mutect2, varscan2
- OR2F2 | c.224C>G p.T75R | Missense Mutation (SNP) | VAF 102/477 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV68832494; called by muse, mutect2, varscan2
- PDE3A | c.2782G>T p.V928F | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.939); catalogued as COSV62967604; called by muse, mutect2, varscan2
- PRSS16 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 59/104 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.372); catalogued as COSV57914749; called by muse, mutect2, varscan2
- SEC11C | c.406G>C p.G136R | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.885); catalogued as COSV55312102; called by muse, mutect2
- SI | c.3301C>A p.Q1101K | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV52265574; called by muse, mutect2, varscan2
- TBX5 | c.1247A>T p.Q416L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV59858376; called by muse, mutect2, varscan2
- TCHH | c.5383A>G p.R1795G | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV64272684; called by muse, mutect2, varscan2
- TDRD7 | c.2158C>T p.R720* | Nonsense Mutation (SNP) | VAF 23/83 reads (28%) | catalogued as rs375523180; called by muse, mutect2, varscan2
- TRIML1 | c.1333T>A p.F445I | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs1247199932, COSV60193244; called by muse, mutect2, varscan2
- USP1 | c.1725C>G p.S575R | Missense Mutation (SNP) | VAF 85/225 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as COSV51995340; called by muse, mutect2, varscan2
- ADAR | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.056); called by muse, mutect2
- G3BP1 | c.653dup p.L219Ifs*7 | Frame Shift Ins (INS) | VAF 24/141 reads (17%) | called by mutect2, pindel, varscan2
- H3C4 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.204); called by muse, mutect2
- IFI44L | c.238_245delinsTGATT p.N80_S82delins* | Nonsense Mutation (DEL) | VAF 26/133 reads (20%) | called by pindel, varscan2*
- IGHV3-16 | c.105del p.S36Pfs*2 | Frame Shift Del (DEL) | VAF 132/685 reads (19%) | called by mutect2, pindel, varscan2
- KLRC2 | c.263T>C p.L88S | Missense Mutation (SNP) | VAF 53/362 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- OGA | c.2068C>A p.Q690K | Missense Mutation (SNP) | VAF 15/293 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- TNIK | c.2149A>T p.I717F | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated (0.7); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- AAK1 | c.2670A>T p.P890= | Silent (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2
- AC104452.1 | c.1056T>C p.Y352= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV56468734; called by muse, mutect2, varscan2
- ADGRV1 | c.2290C>T p.L764= | Silent (SNP) | VAF 60/195 reads (31%) | catalogued as COSV67978175; called by muse, mutect2, varscan2
- AOX1 | c.2961C>G p.S987= | Silent (SNP) | VAF 14/382 reads (4%) | catalogued as COSV65984368, COSV65984650; called by muse, mutect2
- CBLB | c.1335G>A p.P445= | Silent (SNP) | VAF 33/332 reads (10%) | catalogued as rs773229686, COSV51421081; called by muse, mutect2, varscan2
- CNTNAP5 | c.279G>A p.T93= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as rs779127795, COSV70471802; called by muse, mutect2, varscan2
- FRMD4B | c.2385G>A p.K795= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as COSV68328250; called by muse, mutect2, varscan2
- L3MBTL3 | c.1566A>G p.A522= | Silent (SNP) | VAF 47/287 reads (16%) | catalogued as COSV62384231; called by muse, mutect2, varscan2
- MYH7 | c.5796G>A p.L1932= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- NEUROD2 | c.660C>A p.G220= | Silent (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- OR5T2 | c.267T>C p.I89= | Silent (SNP) | VAF 53/153 reads (35%) | catalogued as COSV57587750; called by muse, mutect2, varscan2
- PPP1R21 | c.585T>G p.L195= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV54281662; called by muse, mutect2, varscan2
- SPHKAP | c.1014G>C p.L338= | Silent (SNP) | VAF 29/278 reads (10%) | catalogued as rs1223962158; called by muse, mutect2, varscan2
- ZNF451 | c.919C>T p.L307= | Silent (SNP) | VAF 14/248 reads (6%) | called by muse, mutect2
- DSCR4 | n.427A>G | RNA (SNP) | VAF 41/115 reads (36%) | catalogued as COSV60299347; called by muse, mutect2, varscan2
- SNORD113-9 | n.65A>T | RNA (SNP) | VAF 90/313 reads (29%) | called by muse, mutect2, varscan2
- UROC1 | c.903-595T>C | Intron (SNP) | VAF 9/30 reads (30%) | catalogued as COSV52029992; called by muse, mutect2, varscan2
